Gene-level copy-number profile of tumor specimen TCGA-86-8359-01A from TCGA case TCGA-86-8359, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 52.3 years (19,088 days).
Specimen TCGA-86-8359-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.023c31b7-8e65-4591-874d-508ef388ed51.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-8359-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4fed5701-3f17-41ce-bf1b-1bdc98d83e3f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 968; copy number 2: 19,844; copy number 3: 24,003; copy number 4: 7,748; copy number 5: 2,445; copy number 6: 2,212; copy number 7: 1,212; copy number 8: 1,246; copy number 9: 38; copy number 10: 96; copy number 11: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-8359-01A-11D-2322-01): tumor purity 0.44, ploidy 3.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,594 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:15,903,669–17,284,895, 24 genes, copy number 9: AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.5, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA, AC008164.1, AC008069.1, LINC01866, RN7SKP168, ZFYVE9P2.
- chr2:20,480,844–21,000,917, 12 genes, copy number 9: Y_RNA, AC012065.1, NDUFAF2P1, HS1BP3, AC012065.2, HS1BP3-IT1, RPS25P3, GDF7, AC012065.3, LDAH, LINC02850, AC115619.1.
- chr2:21,922,993–21,923,288, 1 gene, copy number 9: RN7SL117P.
- chr2:22,188,336–22,190,313, 1 gene, copy number 9: AC068044.1.
- chr2:91,736,726–98,313,299, 156 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr5:4,033,713–4,440,259, 3 genes, copy number 7–11: AC025187.1, LINC02063, AC106799.3.
- chr5:8,207,019–10,082,772, 42 genes, copy number 7 (within-gene range 4–7): AC091912.3, LINC02226, AC091965.1, AC091965.3, AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458, AC091953.1, AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3, LINC02199, AC091895.1, AC021088.1, SEMA5A, MIR4636, AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4.
- chr5:51,930,808–58,863,414, 126 genes, copy number 7 (broad region; genes not listed).
- chr5:59,039,761–59,314,800, 2 genes, copy number 7: AC092343.1, AC008833.1.
- chr8:46,028,804–122,985,629, 1,104 genes, copy number 8–10 (broad region; genes not listed).
- chr8:124,450,820–126,008,930, 27 genes, copy number 7: TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1.
- chr8:125,900,951–126,001,001, 3 genes, copy number 7: RNU6-442P, SOD1P3, AC024681.2.
- chr8:127,072,694–138,083,657, 127 genes, copy number 8 (broad region; genes not listed).
- chr8:140,657,900–145,066,685, 196 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr11:28,702,607–50,422,316, 393 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr20:48,821,688–64,313,132, 377 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 269. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
